Somatic mutation profile of tumor specimen MP2PRT-PASPCZ-TMP1-A (aliquot MP2PRT-PASPCZ-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PASPCZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,131 days).
Specimen MP2PRT-PASPCZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 043897a4-9513-41a5-8195-cb46f50110a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPCZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPCZ-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a58461ac-ba79-45a5-a173-8671f30d6591

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR3 | c.8758C>T p.R2920W | Missense Mutation (SNP) | VAF 58/482 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs746195414; called by muse, mutect2, varscan2
- DGKZ | c.2971G>A p.D991N (on ENST00000454345 / NM_001105540.2; = p.D803N on NM_003646.4) | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1422425618; called by muse, mutect2
- GABRA5 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 156/360 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.179); catalogued as rs1418294957; called by muse, mutect2, varscan2
- LRP2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 113/301 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs186568676, COSV99787995; called by muse, mutect2, varscan2
- OR8H3 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 96/428 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755802863, COSV57907234; called by muse, mutect2, varscan2
- ANO3 | c.1824G>A p.M608I | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- FRYL | c.3213C>G p.H1071Q | Missense Mutation (SNP) | VAF 162/388 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.277); called by muse, mutect2
- FRYL | c.3211C>T p.H1071Y | Missense Mutation (SNP) | VAF 158/378 reads (42%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.95); called by muse, mutect2
- KMT2C | c.5161C>T p.Q1721* | Nonsense Mutation (SNP) | VAF 143/340 reads (42%) | called by muse, varscan2
- LOXL3 | c.1709G>T p.W570L | Missense Mutation (SNP) | VAF 151/383 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TRPM6 | c.4841A>G p.E1614G | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- UCP1 | c.838T>G p.S280A | Missense Mutation (SNP) | VAF 142/341 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- HEPACAM | c.1086G>T p.P362= | Silent (SNP) | VAF 24/888 reads (3%) | catalogued as rs1479853505; called by muse, mutect2
- TAS1R2 | c.561C>T p.A187= | Silent (SNP) | VAF 106/363 reads (29%) | catalogued as rs569560287; called by muse, mutect2, varscan2
- TEX13C | c.384G>A p.T128= | Silent (SNP) | VAF 197/215 reads (92%) | called by muse, mutect2, varscan2
- VHL | c.258C>T p.P86= | Silent (SNP) | VAF 281/655 reads (43%) | catalogued as rs781063331, COSV56542787; called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins TCTCTCCA | 5'Flank (INS) | VAF 28/164 reads (17%) | called by mutect2, pindel, varscan2
